Somatic mutation profile of tumor specimen TCGA-AL-A5DJ-01A (aliquot TCGA-AL-A5DJ-01A-11D-A26P-10) from TCGA case TCGA-AL-A5DJ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 55.0 years (20,079 days).
Specimen TCGA-AL-A5DJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 595982d0-9dde-4bee-b1c1-b7a7a0af0ea9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AL-A5DJ-10A (Blood Derived Normal), aliquot TCGA-AL-A5DJ-10A-01D-A26P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc1c290b-32c1-4e4f-83e7-a28034aca01b

The open-access MAF lists 37 somatic variants for this specimen: 23 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 10, 5'Flank 1, 3'Flank 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 192/260 reads (74%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60787768; called by muse, mutect2
- ADCY9 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV53573799; called by muse, mutect2, varscan2
- ANKRD36B | c.58C>A p.H20N | Missense Mutation (SNP) | VAF 73/337 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as COSV51536892; called by muse, mutect2, varscan2
- BIK | c.193G>T p.G65W | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51793611; called by muse, mutect2, varscan2
- C11orf45 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs545751134, COSV57963725; called by muse, mutect2, varscan2
- CD163 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.428); catalogued as COSV63136895; called by muse, mutect2, varscan2
- CLCN3 | c.1619T>C p.I540T | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV61628475; called by muse, mutect2, varscan2
- DNAAF2 | c.2478C>A p.F826L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.795); catalogued as COSV53566970; called by muse, mutect2, varscan2
- FRMPD3 | c.4067G>C p.R1356T | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV52196994; called by muse, mutect2
- GABRA3 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated, low confidence (0.41); PolyPhen possibly damaging (0.885); catalogued as COSV64804865; called by muse, mutect2, varscan2
- GCDH | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1333480915, COSV53434825; called by muse, mutect2, varscan2
- KCNK9 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 82/196 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.174); catalogued as COSV57280392; called by muse, mutect2, varscan2
- KMT2C | c.11436G>T p.E3812D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV100072817, COSV51498734; called by muse, mutect2, varscan2
- MAGEC1 | c.2956G>T p.G986W | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53580768; called by muse, mutect2, varscan2
- MEGF6 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs1274127938, COSV53895572; called by muse, mutect2, varscan2
- NDRG4 | c.653C>T p.T218M (on ENST00000570248 / NM_001378344.1; = p.T250M on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.861); catalogued as rs200391051; called by muse, mutect2, varscan2
- NUP205 | c.2243G>A p.R748H | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.053); catalogued as rs375295025; called by muse, mutect2, varscan2
- PCBP4 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 54/270 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV59055985; called by muse, mutect2, varscan2
- QARS1 | c.1982T>A p.L661Q | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60276148; called by muse, mutect2, varscan2
- RANBP2 | c.9130T>G p.L3044V | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV51708204; called by muse, mutect2, varscan2
- XRN1 | c.4676C>T p.S1559L | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.035); catalogued as rs552700387, COSV53810653; called by muse, mutect2, varscan2
- ZNF502 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV56075037; called by muse, mutect2, varscan2
- ZNF679 | c.50C>A p.T17K | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV55381661; called by muse, mutect2
- ADCY9 | c.1491C>T p.C497= | Silent (SNP) | VAF 131/182 reads (72%) | catalogued as rs759050637, COSV53574048; called by muse, mutect2, varscan2
- DNAAF4 | c.795A>G p.K265= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV58251536; called by muse, mutect2, varscan2
- EIF2AK3 | c.318A>G p.V106= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV57551895; called by muse, mutect2, varscan2
- H2AC8 | c.360G>A p.K120= | Silent (SNP) | VAF 86/136 reads (63%) | catalogued as rs1445364916, COSV55127037, COSV55127859, COSV99773137; called by muse, mutect2, varscan2
- HTR3C | c.978C>T p.T326= | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as rs751045506, COSV59177239; called by muse, mutect2, varscan2
- MYCN | c.957C>T p.I319= | Silent (SNP) | VAF 100/435 reads (23%) | catalogued as COSV55261051; called by muse, mutect2, varscan2
- OR51S1 | c.960T>A p.G320= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as COSV59060033; called by muse, mutect2, varscan2
- PIK3C2G | c.1249C>T p.L417= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV56832151; called by muse, mutect2, varscan2
- PNPLA1 | c.150G>A p.A50= | Silent (SNP) | VAF 82/97 reads (85%) | catalogued as rs908305687, COSV57237940; called by muse, mutect2, varscan2
- ZC3H6 | c.1044C>G p.S348= | Silent (SNP) | VAF 49/156 reads (31%) | catalogued as COSV59670445; called by muse, mutect2, varscan2
- GPER1 | c.*131_*132del | 3'UTR (DEL) | VAF 45/120 reads (38%) | called by pindel, varscan2
- GPR6 | chr6:109980322 A>G | 3'Flank (SNP) | VAF 45/213 reads (21%) | catalogued as COSV99254536; called by muse, mutect2, varscan2
- PBDC1 | c.-30G>A | 5'UTR (SNP) | VAF 14/389 reads (4%) | catalogued as rs782169935, COSV100972848; called by muse, mutect2
- SUCO | chr1:172532595 G>T | 5'Flank (SNP) | VAF 46/303 reads (15%) | catalogued as rs528809446, COSV55265429; called by muse, mutect2, varscan2
